Gene-level copy-number profile of tumor specimen TCGA-DY-A1DG-01A from TCGA case TCGA-DY-A1DG, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Age at diagnosis: 75.0 years (27,396 days).
Specimen TCGA-DY-A1DG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.e93727f0-8de7-4e92-9659-54de8277eb74.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DY-A1DG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a91cf977-b742-49c1-9c25-2f32c66a2ec2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 1,853; copy number 2: 15,113; copy number 3: 30,626; copy number 4: 10,939; copy number 5: 706; copy number 6: 218; copy number 7: 328; copy number 8: 4; copy number 9: 12; copy number 18: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DY-A1DG-01A-11D-A151-01): tumor purity 0.92, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:106,815,197–107,670,937, 3 genes (within-gene range 0–2): LINC01950, PSMC1P5, EFNA5.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 361 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:40,271,566–40,387,590, 4 genes, copy number 7 (within-gene range 5–7): AL139275.2, TDRG1, LINC00951, AL139275.1.
- chr6:41,228,339–41,406,561, 12 genes, copy number 9: TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2.
- chr8:38,269,704–38,382,272, 1 gene, copy number 18 (within-gene range 3–18): NSD3.
- chr8:38,335,981–38,973,912, 16 genes, copy number 18 (within-gene range 3–18): AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2.
- chr20:31,303,212–36,870,402, 209 genes, copy number 7 (broad region; genes not listed).
- chr20:37,571,103–38,166,578, 12 genes, copy number 7 (within-gene range 5–7): LINC01746, GLRXP1, LINC00489, AL162293.1, CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2.
- chr20:46,557,823–48,136,844, 38 genes, copy number 7–8 (within-gene range 6–8): SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1, SULF2, AL354813.1, RNU7-173P, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, AL357558.3, LINC01522, LINC01523, AL139351.2, AL139351.3, AL139351.1, AL136102.1.
- chr20:48,624,252–51,131,667, 69 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,853. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
